Surgical pathology report (de-identified scan), TCGA case TCGA-KL-8333, project TCGA-KICH (Kidney Chromophobe), tissue source site MSKCC, specimen TCGA-KL-8333-01A (Primary Tumor).

[page 1 of 2]
Clinical Diagnosis & History:

year old male with left renal mass.

Specimens Submitted:

1: KIDNEY AND ADRENAL GLAND, LEFT, TOTAL NEPHRECTOMY, ADRENALECTOMY

DIAGNOSIS:

1. KIDNEY AND ADRENAL GLAND, LEFT, TOTAL NEPHRECTOMY, ADRENALECTOMY:

Tumor Type:

Renal cell carcinoma - Chromophobe type

Tumor Size:

Greatest diameter is 15.5 cm.

Local Invasion (for renal cortical types):

Not Identified

Renal Vein Invasion:

Not identified

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

Unremarkable

Adrenal Gland:

Not involved

Lymph Nodes:

Free of tumor

Number of nodes examined:5

Staging for renal cell carcinoma/oncocytoma:

pT2 Tumor >7.0 cm in greatest dimension limited to the kidney

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

[page 2 of 2]
Gross Description:

1) The specimen is received fresh for frozen, labeled "Left kidney, adrenal and hilar lymph nodes". It consists of a grossly recognizable kidney whose appearance is markedly altered by a large mass localized to the lower pole. Attached to the upper pole of the kidney is a portion of fatty tissue investing a grossly recognizable adrenal gland. An attached segment of ureter is identified at the hilum. The overall measurements of the specimen are 22.0 x 14.0 x 8.5 cm. The specimen weighs altogether 905 gm. The specimen is bivalved to demonstrate a large coarsely lobulated well-circumscribed and possibly encapsulated tumor with fleshy, homogenously pink-tan cut surface with multiple scattered small cystic areas. The tumor measures 15.5 x 13.0 x 8.5 cm. The tumor replaces the entire lower pole of the kidney. It appears to be pushing on the renal sinus fat but does not seem to invade it or extend into the collecting system. No macroscopic vascular invasion is noted. The tumor appears to grossly extend into the perirenal fat but not through the gerota's fascia. The remainder of the kidney is grossly unremarkable. The adrenal gland is dissected off the kidney. It measures 5.3 x 2.6 x 0.9 cm, weighs 7 gm and is grossly unremarkable both from outside and on the cross-section. The hilar fat is searched for lymph nodes. Several possible lymph nodes are dissected. Samples of tumor and normal kidney tissue are submitted for [REDACTED] Gross photographs are taken. Representative sections are submitted for frozen section diagnosis and paraffin blocks.

Summary of Sections:

FSC - frozen section control

M - margin

TC - tumor to capsule

TK - tumor to kidney

NLK - normal to kidney

AD - adrenal

PLN - probable lymph nodes

Summary of Sections:

Part 1: KIDNEY AND ADRENAL GLAND, LEFT, TOTAL NEPHRECTOMY, ADRENALECTOMY

Block	Sect. Site	PCs
1	ad	1
1	fsc	1
1	m	3
1	nlk	1
2	pln	4
4	tc	6
5	tk	5

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

- 1) FROZEN SECTION DIAGNOSIS: RENAL CORTICAL TUMOR. FAVOR CHROMOPHOBE RENAL CELL CARCINOMA. [REDACTED]
PERMANENT DIAGNOSIS: SAME
- [REDACTED]

Source: NCI Genomic Data Commons file 21bd208f-b1df-4ae8-bc96-4c1353683e82 (TCGA-KL-8333.46B555ED-5ABE-4A4D-99AD-F5BB5D46A473.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).